Gene-level copy-number profile of tumor specimen TCGA-AZ-4614-01A from TCGA case TCGA-AZ-4614, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-AZ-4614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.221d947f-2f8c-45ff-97de-64229a2158ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-4614-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12fd841b-8d10-41bd-9c1d-764786e637ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 119; copy number 2: 9,674; copy number 3: 9,029; copy number 4: 33,897; copy number 5: 2,819; copy number 6: 3,705; copy number 7: 5; copy number 8: 263; copy number 10: 21; copy number 11: 44; copy number 13: 23; copy number 14: 101; copy number 20: 84; copy number 24: 14; copy number 26: 6; copy number 30: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-4614-01A-01D-1406-01): tumor purity 0.86, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr9:25,579,657–26,118,408, 5 genes: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 154 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,431,191–89,590,097, 8 genes, copy number 11: Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr6:135,181,308–135,219,173, 1 gene, copy number 10 (within-gene range 5–10): MYB.
- chr6:135,239,160–135,260,933, 2 genes, copy number 10: MIR548A2, AL023693.1.
- chr8:36,764,445–37,779,768, 23 genes, copy number 13: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP.
- chr20:43,540,171–46,432,985, 120 genes, copy number 11–20 (within-gene range 5–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
